Gene-level copy-number profile of tumor specimen TCGA-49-4506-01A from TCGA case TCGA-49-4506, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.8 years (25,132 days).
Specimen TCGA-49-4506-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.52621c1e-ded0-4d9e-b47c-fb0aff4a68f6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-4506-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/112d73eb-ae52-4b78-9851-c33d99e8b147

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,432; copy number 2: 19,811; copy number 3: 14,993; copy number 4: 16,000; copy number 5: 3,964; copy number 6: 2,619.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-4506-01A-01D-1204-01): tumor purity 0.25, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,583 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 6 (broad region; genes not listed).
- chr7:6,409,126–62,275,678, 929 genes, copy number 5 (broad region; genes not listed).
- chr14:36,677,921–37,172,606, 1 gene, copy number 6 (within-gene range 4–6): SLC25A21.
- chr14:36,952,309–38,041,442, 14 genes, copy number 6: MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1.
- chr15:19,878,555–101,933,350, 2,215 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–30,214,976, 560 genes, copy number 5 (broad region; genes not listed).
- chr20:55,607,852–64,313,132, 260 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
